Somatic mutation profile of tumor specimen MMRF_2001_1_BM_CD138pos (aliquot MMRF_2001_1_BM_CD138pos_T1_KHS5U_L08071) from MMRF case MMRF_2001, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.6 years (21,056 days).
Specimen MMRF_2001_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30d30b1f-be91-4ee4-820c-7bc2ce3548f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2001_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2001_1_PB_Whole_C2_KHS5U_L08072; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a32b0d1-2835-41a4-b489-588eb778cfd4

The open-access MAF lists 118 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 26, Intron 16, Silent 14, 5'Flank 5, 3'Flank 3, 5'UTR 3, Frame Shift Del 3, RNA 2, Splice Region 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAF1A | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56676303; called by muse, mutect2, varscan2
- COL1A1 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs142128554; called by muse, mutect2, varscan2
- COL1A1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as CM137813; called by muse, varscan2
- EVPL | c.3857G>A p.R1286H | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs868326369; called by muse, mutect2, varscan2
- GALNT5 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758078817, COSV52040004; called by muse, mutect2, varscan2
- IGHV2-70 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs372477786; called by muse, varscan2
- PLEKHM3 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV66817054; called by muse, mutect2, varscan2
- POLI | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs146107490; called by muse, mutect2, varscan2
- PSD3 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.052); catalogued as rs201831146; called by muse, mutect2, varscan2
- RFX2 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs769822837; called by muse, mutect2, varscan2
- S1PR5 | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs767304329; called by muse, mutect2, varscan2
- SLC25A46 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756258729, COSV63507156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SYTL3 | c.1646G>A p.S549N (on ENST00000611299 / NM_001242394.1; = p.S481N on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.628); catalogued as rs532435360; called by muse, mutect2, varscan2
- YARS2 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764784116; called by muse, mutect2, varscan2
- ZIC1 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as rs1186571686; called by muse, varscan2
- ZNF268 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 311/322 reads (97%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs377003792; called by muse, mutect2, varscan2
- ZNF534 | c.1738C>T p.R580* (on ENST00000332323 / NM_001143939.3; = p.R567* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 62/263 reads (24%) | catalogued as rs578064178, COSV56514210; called by muse, mutect2, varscan2
- ACTB | c.-27-8G>C | Splice Region (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- AL031777.2 | c.503C>G p.A168G | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.2957A>C p.E986A | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP32 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CDH11 | c.2381A>T p.D794V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, varscan2
- CNBD1 | c.1229A>T p.Q410L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CNTN5 | c.3127A>C p.I1043L | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CYP2S1 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNAJC19 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DUSP2 | c.471A>T p.K157N | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- EYS | c.1141A>T p.N381Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GPR108 | c.1434G>A p.Q478= (on ENST00000264080 / NM_001080452.1; = p.Q236= on NM_020171.2) | Splice Region (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- GPRASP2 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GSAP | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HLTF | c.2241_2245del p.M748Vfs*9 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.1961A>T p.K654M | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGHV2-70D | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.165); called by muse, varscan2
- IGHV3-23 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR2AT4 | c.23A>C p.E8A | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH10 | c.2129C>A p.T710N | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- POLR2A | c.917A>C p.D306A | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.074); called by muse, mutect2
- RACK1 | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RPL10 | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RPN1 | c.199_202del p.T67Lfs*21 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | called by mutect2, pindel, varscan2
- TEX45 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1826T>A p.I609N | Missense Mutation (SNP) | VAF 85/136 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- USH2A | c.6977A>T p.E2326V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WNT10A | c.1098C>G p.S366R | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX3 | c.8084G>A p.R2695Q | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF337 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF473 | c.1698A>T p.K566N | Missense Mutation (SNP) | VAF 10/344 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2
- ATP2A2 | c.2988G>A p.E996= | Silent (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- FAM131C | c.504G>A p.S168= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs756525734; called by muse, varscan2
- IGHV1-69D | c.72G>A p.V24= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as rs1169764693; called by mutect2, varscan2
- ITPRIPL2 | c.324G>A p.E108= | Silent (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- NUP153 | c.1320T>A p.S440= | Silent (SNP) | VAF 71/232 reads (31%) | called by muse, mutect2, varscan2
- OAS3 | c.2148G>A p.L716= | Silent (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- PYGM | c.840G>A p.L280= | Silent (SNP) | VAF 67/101 reads (66%) | called by muse, mutect2, varscan2
- RYR2 | c.14103T>C p.I4701= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs1367823440; called by muse, mutect2, varscan2
- SAMD1 | c.252G>A p.R84= | Silent (SNP) | VAF 71/134 reads (53%) | catalogued as rs1380461716; called by muse, mutect2, varscan2
- TBRG1 | c.30G>T p.S10= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs755808629, COSV52514312; called by muse, mutect2, varscan2
- TGFB2 | c.1143G>T p.V381= | Silent (SNP) | VAF 61/138 reads (44%) | called by muse, mutect2, varscan2
- TLL2 | c.1605C>A p.I535= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- ZC3H12C | c.1437T>C p.T479= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- ZIC1 | c.123C>G p.A41= | Silent (SNP) | VAF 70/209 reads (33%) | catalogued as COSV51551374; called by muse, varscan2
- ABCC12 | c.3196-15G>A | Intron (SNP) | VAF 23/42 reads (55%) | catalogued as rs372682610; called by muse, mutect2, varscan2
- ACP3 | c.*413del | 3'UTR (DEL) | VAF 22/38 reads (58%) | catalogued as rs759194452; called by mutect2, varscan2
- ACTB | c.-27-279C>A | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- ADPGK | c.643+31A>T | Intron (SNP) | VAF 92/419 reads (22%) | catalogued as rs1259038033; called by muse, mutect2, varscan2
- AFDN | chr6:167970004 T>G | 3'Flank (SNP) | VAF 68/239 reads (28%) | called by muse, mutect2, varscan2
- AGFG1 | c.-143C>G | 5'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- ANKRD13C | c.*1001A>G | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- ARSJ | c.-387C>T | 5'UTR (SNP) | VAF 34/198 reads (17%) | called by muse, mutect2, varscan2
- BACH2 | c.*211A>G | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- C1QL3 | chr10:16521924 A>C | 5'Flank (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65882234 C>A | 3'Flank (SNP) | VAF 30/118 reads (25%) | catalogued as rs1260488384; called by muse, mutect2, varscan2
- CDKN2AIPNL | c.240-725_240-724del | Intron (DEL) | VAF 46/183 reads (25%) | called by mutect2, pindel, varscan2
- CEP78 | c.*7420G>A | 3'UTR (SNP) | VAF 50/70 reads (71%) | called by muse, mutect2, varscan2
- CHRNA7 | c.*2142A>C | 3'UTR (SNP) | VAF 51/61 reads (84%) | called by muse, mutect2, varscan2
- CHRND | chr2:232526017 del TGG | 5'Flank (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- CHTF18 | c.*19T>C | 3'UTR (SNP) | VAF 45/83 reads (54%) | catalogued as rs768840030; called by muse, mutect2, varscan2
- CLINT1 | c.*971T>C | 3'UTR (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- DDX39B | c.-3+161C>G | Intron (SNP) | VAF 57/184 reads (31%) | called by muse, mutect2, varscan2
- FEM1C | c.*532G>A | 3'UTR (SNP) | VAF 32/103 reads (31%) | catalogued as rs1226463729; called by muse, mutect2, varscan2
- GRIA4 | c.1269+1588del | Intron (DEL) | VAF 25/85 reads (29%) | called by mutect2, pindel, varscan2
- GTDC1 | chr2:143945900 T>A | 3'Flank (SNP) | VAF 33/81 reads (41%) | catalogued as rs920277032; called by muse, mutect2, varscan2
- KCNK5 | c.*520C>T | 3'UTR (SNP) | VAF 32/117 reads (27%) | catalogued as rs911183741; called by muse, mutect2, varscan2
- KCTD21 | c.*417A>T | 3'UTR (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- LINC00687 | n.586G>A | RNA (SNP) | VAF 51/93 reads (55%) | catalogued as rs1354387418; called by muse, mutect2, varscan2
- LRCH3 | c.2209-394T>G | Intron (SNP) | VAF 37/97 reads (38%) | catalogued as rs893620975; called by muse, mutect2, varscan2
- LTBP3 | c.1531+40C>A | Intron (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- LYSMD2 | c.*382G>T | 3'UTR (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- MAFB | c.*827C>T | 3'UTR (SNP) | VAF 10/35 reads (29%) | catalogued as rs982331881; called by muse, mutect2, varscan2
- MAP6 | c.1316+233G>T | Intron (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- MGAT4EP | n.2638T>A | RNA (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- MICAL2 | c.3334+266G>A | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851253 A>G | 5'Flank (SNP) | VAF 54/139 reads (39%) | catalogued as rs762713616; called by muse, mutect2, varscan2
- MMD2 | c.*185G>A | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- MOCS2 | chr5:53109843 T>C | 5'Flank (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- NPNT | c.*1650A>G | 3'UTR (SNP) | VAF 212/318 reads (67%) | catalogued as rs548026181; called by muse, mutect2, varscan2
- NT5M | c.*15C>T | 3'UTR (SNP) | VAF 19/36 reads (53%) | catalogued as rs752604043; called by muse, mutect2, varscan2
- PER1 | c.2461+101G>A | Intron (SNP) | VAF 52/158 reads (33%) | called by muse, mutect2
- PLCL1 | c.-159T>C | 5'UTR (SNP) | VAF 88/172 reads (51%) | called by mutect2, varscan2
- PTP4A2 | c.*1545T>C | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- PTPRN2 | c.*1243C>T | 3'UTR (SNP) | VAF 31/118 reads (26%) | called by mutect2, varscan2
- PTTG1IP | c.*725T>C | 3'UTR (SNP) | VAF 16/34 reads (47%) | catalogued as rs199803274; called by muse, mutect2, varscan2
- SEMA3C | c.*1633A>T | 3'UTR (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- SERPINA1 | c.-4-9G>A | Intron (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- SERPINE2 | c.*127G>A | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- SLC31A1 | c.*1511G>A | 3'UTR (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- SLC7A9 | c.749+33C>T | Intron (SNP) | VAF 91/203 reads (45%) | catalogued as rs370792507; called by muse, mutect2, varscan2
- SMO | c.*455A>G | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- SOCS4 | c.*540T>G | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- TBCK | c.*1736_*1740del | 3'UTR (DEL) | VAF 47/140 reads (34%) | catalogued as rs1266331453; called by mutect2, pindel, varscan2
- TRPS1 | c.*214del | 3'UTR (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- TST | c.-22+64G>T | Intron (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- VMP1 | c.1077+64C>T | Intron (SNP) | VAF 53/135 reads (39%) | called by muse, mutect2
- VMP1 | c.1077+66C>T | Intron (SNP) | VAF 55/137 reads (40%) | catalogued as rs185222973; called by muse, mutect2
- ZBTB10 | c.*3217A>G | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- ZNF606 | chr19:58005729 ins T | 5'Flank (INS) | VAF 85/213 reads (40%) | called by mutect2, pindel, varscan2
